Somatic mutation profile of tumor specimen 0DNGGR from CCDI case PBCBGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 3.9 years (1,430 days).
Specimen 0DNGGR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e95bb513-dda1-4e2b-8c6d-3fd953f1a083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNGG7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf5bc848-5f2f-40ba-b356-02170b52c149

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.11542G>A p.E3848K | Missense Mutation (SNP) | VAF 276/597 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs777083781, COSV55575153; called by muse, mutect2, varscan2
- SHANK1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 276/628 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV53248400; called by muse, mutect2, varscan2
- ETV6 | c.416_417del p.S139Yfs*14 | Frame Shift Del (DEL) | VAF 219/715 reads (31%) | called by pindel, varscan2
- KLHL15 | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 142/166 reads (86%) | called by muse, mutect2, varscan2
- PDE2A | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 215/522 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- H1-7 | c.447C>T p.A149= | Silent (SNP) | VAF 272/651 reads (42%) | catalogued as rs375416367; called by muse, mutect2, varscan2
- ZNF692 | c.1170C>T p.I390= | Silent (SNP) | VAF 26/786 reads (3%) | called by muse, mutect2
- PMM1 | c.374+57G>T | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- TRPM1 | c.-49G>A | 5'UTR (SNP) | VAF 170/365 reads (47%) | called by muse, mutect2, varscan2
- ZNF806 | n.295-2215C>G | Intron (SNP) | VAF 20/722 reads (3%) | called by muse, mutect2
